Somatic mutation profile of tumor specimen TCGA-R6-A8WG-01A (aliquot TCGA-R6-A8WG-01A-11D-A37C-09) from TCGA case TCGA-R6-A8WG, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; Tumor grade: G3; Age at diagnosis: 60.5 years (22,093 days).
Specimen TCGA-R6-A8WG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bc865de1-66b9-4766-8c03-f3b107f1c9aa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-R6-A8WG-10A (Blood Derived Normal), aliquot TCGA-R6-A8WG-10A-01D-A37F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4778df07-cc7f-428a-8f7d-a0c20b07f276

The open-access MAF lists 113 somatic variants for this specimen: 78 protein-altering or splice-affecting, 29 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 69, Silent 29, Intron 4, Nonsense Mutation 3, Frame Shift Del 2, Splice Site 2, 5'UTR 1, Frame Shift Ins 1, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 8/61 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SCN5A | c.4895G>A p.R1632H (on ENST00000333535 / NM_198056.3; = p.R1631H on NM_000335.5) | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs199473286, CM033023, COSV61122853; ClinVar: not provided / pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 14/19 reads (74%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS18 | c.1327G>A p.G443S | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51400539; called by muse, mutect2, varscan2
- ADGRE1 | c.1357T>G p.L453V | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as rs146387629; called by muse, mutect2, varscan2
- ADGRL2 | c.3140T>G p.L1047R (on ENST00000370717 / NM_001366005.1; = p.L1034R on NM_012302.4) | Missense Mutation (SNP) | VAF 39/78 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54649767; called by muse, mutect2, varscan2
- APEH | c.1162C>G p.L388V | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.023); catalogued as rs1164777072; called by muse, mutect2, varscan2
- ARFGEF3 | c.2722C>T p.R908W | Missense Mutation (SNP) | VAF 25/35 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs763602394, COSV52450100; called by muse, mutect2, varscan2
- ATAD2B | c.1066G>A p.A356T | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs1301428784; called by muse, mutect2, varscan2
- ATG9A | c.691C>T p.R231C | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs200810317, COSV100772695; called by muse, mutect2, varscan2
- CCR1 | c.433C>T p.R145W | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.756); catalogued as rs777872590; called by muse, mutect2, varscan2
- CNTN6 | c.68del p.L23* | Frame Shift Del (DEL) | VAF 38/75 reads (51%) | catalogued as COSV63175010; called by mutect2, pindel, varscan2
- DLG5 | c.1568G>A p.R523Q | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1484191413; called by muse, mutect2, varscan2
- EFCAB6 | c.2039C>A p.T680N | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.013); catalogued as rs764808112; called by muse, mutect2, varscan2
- HAPLN4 | c.551C>T p.A184V | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.784); catalogued as COSV52271042; called by muse, mutect2, varscan2
- HSPA12A | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated (0.36); PolyPhen benign (0.065); catalogued as rs1047363608; called by muse, mutect2, varscan2
- IFFO1 | c.254G>A p.R85H | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV59109523; called by muse, mutect2, varscan2
- IL18RAP | c.162_181del p.H55Tfs*8 | Frame Shift Del (DEL) | VAF 6/36 reads (17%) | catalogued as rs777947995; called by mutect2, varscan2
- INTS8 | c.2305G>A p.V769I | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.646); catalogued as rs1295992350; called by muse, mutect2, varscan2
- LRP1B | c.3440C>A p.T1147N | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.251); catalogued as COSV67221987; called by muse, mutect2, varscan2
- MAP2K1 | c.199G>T p.D67Y | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as CM076269, COSV61068427, COSV61072298; called by muse, mutect2, varscan2
- NFATC1 | c.1439C>T p.T480M | Missense Mutation (SNP) | VAF 25/39 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs202124742, COSV53701166; called by muse, mutect2, varscan2
- OCA2 | c.2440T>C p.F814L | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.348); catalogued as COSV62340362; called by muse, mutect2, varscan2
- PLA2G15 | c.611C>T p.T204M | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.197); catalogued as rs777101572, COSV99547216; called by muse, mutect2, varscan2
- POM121L12 | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as rs747363850, COSV68692362, COSV68693283; called by muse, mutect2, varscan2
- PTPRB | c.4988G>A p.R1663Q | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.325); catalogued as rs139546127, COSV54237615; called by muse, mutect2, varscan2
- RGS7 | c.823A>G p.K275E | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV58545966; called by muse, mutect2, varscan2
- SBNO2 | c.1109G>A p.R370Q | Missense Mutation (SNP) | VAF 36/50 reads (72%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.714); catalogued as rs757990173; called by muse, mutect2, varscan2
- SCN1A | c.1492A>G p.R498G | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.346); catalogued as CM096093; called by muse, mutect2, varscan2
- SCNN1A | c.1807C>T p.Q603* | Nonsense Mutation (SNP) | VAF 29/108 reads (27%) | catalogued as rs766773131; called by muse, mutect2, varscan2
- SLC24A4 | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs748090494, COSV100104560; called by muse, mutect2, varscan2
- TBC1D32 | c.317+1G>A p.X106_splice | Splice Site (SNP) | VAF 29/39 reads (74%) | catalogued as rs1237824922; called by muse, mutect2, varscan2
- TBL3 | c.305G>A p.R102H | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs776455995; called by muse, mutect2, varscan2
- VAT1L | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.043); catalogued as rs1444597534; called by muse, mutect2, varscan2
- ZNF775 | c.557C>T p.S186F | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.51); catalogued as COSV61613235; called by muse, mutect2, varscan2
- ABCB4 | c.236G>A p.G79E | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- APOB | c.9632dup p.N3211Kfs*14 | Frame Shift Ins (INS) | VAF 16/60 reads (27%) | called by mutect2, varscan2
- AUP1 | c.449G>C p.R150T | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.57); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- C2CD2 | c.1292T>G p.V431G | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CAMK1 | c.533C>A p.A178D | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CFAP206 | c.125T>G p.L42R | Missense Mutation (SNP) | VAF 35/61 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- COL11A1 | c.724G>A p.D242N | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.516); called by muse, mutect2
- CUL9 | c.4531G>A p.A1511T | Missense Mutation (SNP) | VAF 21/29 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- DNAH7 | c.3684G>T p.L1228F | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNMBP | c.3151A>G p.I1051V | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- DRP2 | c.1358C>A p.A453D | Missense Mutation (SNP) | VAF 40/43 reads (93%) | SIFT deleterious (0); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- DUSP9 | c.458T>G p.V153G | Missense Mutation (SNP) | VAF 28/34 reads (82%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2
- DYNC2H1 | c.5663C>G p.T1888S | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- EFCAB6 | c.775C>T p.Q259* | Nonsense Mutation (SNP) | VAF 17/82 reads (21%) | called by muse, mutect2, varscan2
- EID2B | c.17G>A p.G6E | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ERBB2 | c.2515G>A p.V839M | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.471); called by muse, mutect2, varscan2
- ESPL1 | c.2008A>G p.R670G | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FAR2 | c.888-1G>A p.X296_splice | Splice Site (SNP) | VAF 13/37 reads (35%) | called by muse, mutect2, varscan2
- HMGCS1 | c.1555G>A p.E519K | Missense Mutation (SNP) | VAF 48/120 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.01); called by muse, varscan2
- KRTAP10-11 | c.361G>T p.G121W | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); called by muse, mutect2
- NAV3 | c.4391C>T p.P1464L | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NCKAP1 | c.2366C>G p.T789R | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- NIPAL4 | c.1022T>G p.V341G | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- OBSCN | c.10974G>C p.W3658C | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); called by mutect2, varscan2
- OR2AK2 | c.260C>T p.S87L | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT tolerated (0.38); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- OR4A15 | c.314T>G p.F105C | Missense Mutation (SNP) | VAF 35/53 reads (66%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.317); called by muse, mutect2, varscan2
- OR5K4 | c.910A>T p.N304Y | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PCLO | c.12413G>T p.S4138I | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- PCNX4 | c.3112A>C p.S1038R (on ENST00000406854 / NM_001330177.2; = p.S804R on NM_022495.5) | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- PIGR | c.160T>C p.Y54H | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PKHD1L1 | c.4174T>C p.F1392L | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- PLXNB1 | c.2134G>C p.E712Q | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.037); called by muse, mutect2
- PRPF40A | c.2141_2143del p.K714del | In Frame Del (DEL) | VAF 12/35 reads (34%) | called by pindel, varscan2
- RBM27 | c.1924C>A p.L642I | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- RHOJ | c.581T>G p.I194S | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- RIMS1 | c.4684A>C p.S1562R | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); called by muse, mutect2, varscan2
- SETBP1 | c.4274A>C p.K1425T | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- SF3B3 | c.275A>G p.Y92C | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SI | c.4020C>A p.N1340K | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- SLC12A5 | c.2613C>G p.H871Q (on ENST00000454036 / NM_001134771.2; = p.H848Q on NM_020708.5) | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- TTN | c.74748A>C p.Q24916H (on ENST00000591111; = p.Q17492H on NM_003319.4) | Missense Mutation (SNP) | VAF 19/61 reads (31%) | PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- ZNF479 | c.255A>C p.K85N | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ZNF99 | c.1825A>T p.R609* | Nonsense Mutation (SNP) | VAF 21/68 reads (31%) | called by muse, mutect2, varscan2
- AC104389.6 | c.474A>C p.A158= | Silent (SNP) | VAF 40/55 reads (73%) | called by muse, mutect2, varscan2
- ADAMTS19 | c.2602A>C p.R868= | Silent (SNP) | VAF 19/37 reads (51%) | catalogued as COSV50736480; called by muse, mutect2, varscan2
- ARIH2 | c.744G>A p.Q248= | Silent (SNP) | VAF 6/29 reads (21%) | called by muse, mutect2, varscan2
- ARSF | c.1230C>T p.V410= | Silent (SNP) | VAF 28/36 reads (78%) | catalogued as rs201866054, COSV100839442; called by muse, mutect2, varscan2
- ATP10D | c.123T>C p.S41= | Silent (SNP) | VAF 19/37 reads (51%) | called by muse, mutect2, varscan2
- CCNK | c.1134C>T p.L378= | Silent (SNP) | VAF 32/109 reads (29%) | catalogued as rs1396974445, COSV66274989; called by muse, mutect2, varscan2
- CCSER2 | c.1200G>A p.S400= | Silent (SNP) | VAF 16/27 reads (59%) | catalogued as rs764559431, COSV99825348; called by muse, mutect2, varscan2
- DMXL2 | c.2073A>G p.R691= | Silent (SNP) | VAF 11/46 reads (24%) | called by muse, mutect2, varscan2
- ETV4 | c.51C>A p.T17= | Silent (SNP) | VAF 14/91 reads (15%) | called by muse, mutect2, varscan2
- EVC2 | c.2226G>A p.S742= | Silent (SNP) | VAF 20/33 reads (61%) | catalogued as rs1225003407, COSV60401823; called by muse, mutect2, varscan2
- HSD11B2 | c.966A>T p.V322= | Silent (SNP) | VAF 13/39 reads (33%) | called by muse, mutect2, varscan2
- IQCE | c.645G>C p.L215= | Silent (SNP) | VAF 8/26 reads (31%) | called by muse, mutect2
- KLHL15 | c.225A>G p.K75= | Silent (SNP) | VAF 3/34 reads (9%) | called by muse, mutect2
- LAMA1 | c.3420C>T p.R1140= | Silent (SNP) | VAF 20/45 reads (44%) | catalogued as rs144126568; called by muse, mutect2, varscan2
- LRP1B | c.7734A>G p.G2578= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as COSV67240631; called by muse, mutect2, varscan2
- MAP3K6 | c.3306C>T p.F1102= | Silent (SNP) | VAF 21/95 reads (22%) | catalogued as rs752156772; called by muse, mutect2, varscan2
- MICAL2 | c.3939G>A p.S1313= | Silent (SNP) | VAF 32/54 reads (59%) | catalogued as rs182474608; called by muse, mutect2, varscan2
- NEBL | c.1923A>G p.E641= | Silent (SNP) | VAF 8/54 reads (15%) | called by muse, mutect2, varscan2
- NTNG2 | c.948C>T p.C316= | Silent (SNP) | VAF 43/67 reads (64%) | catalogued as rs200407107, COSV62365721; called by muse, mutect2, varscan2
- OR10G8 | c.396C>T p.T132= | Silent (SNP) | VAF 37/68 reads (54%) | catalogued as rs760036197; called by muse, mutect2, varscan2
- PLXNA1 | c.5085C>T p.D1695= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as rs775027299; called by muse, mutect2, varscan2
- RADIL | c.939G>T p.G313= | Silent (SNP) | VAF 22/94 reads (23%) | called by muse, mutect2, varscan2
- SGIP1 | c.1020A>G p.P340= | Silent (SNP) | VAF 21/50 reads (42%) | catalogued as COSV99390404; called by muse, mutect2, varscan2
- ST6GAL2 | c.459C>A p.P153= | Silent (SNP) | VAF 12/25 reads (48%) | catalogued as COSV64529387; called by muse, mutect2, varscan2
- SYP | c.255C>T p.P85= | Silent (SNP) | VAF 13/17 reads (76%) | called by muse, mutect2, varscan2
- ULK4 | c.3444G>T p.L1148= | Silent (SNP) | VAF 11/51 reads (22%) | called by muse, mutect2, varscan2
- USP13 | c.1941G>A p.L647= | Silent (SNP) | VAF 64/139 reads (46%) | called by muse, mutect2, varscan2
- ZNF425 | c.762C>T p.S254= | Silent (SNP) | VAF 16/32 reads (50%) | called by muse, mutect2, varscan2
- ZNF536 | c.2673T>G p.P891= | Silent (SNP) | VAF 19/45 reads (42%) | called by muse, mutect2, varscan2
- C1orf116 | c.-1G>A | 5'UTR (SNP) | VAF 22/41 reads (54%) | catalogued as rs1478069067, COSV100848048; called by muse, mutect2, varscan2
- MAGEC3 | c.1124-161G>T | Intron (SNP) | VAF 36/39 reads (92%) | called by muse, mutect2, varscan2
- NRG1 | c.502+31294A>C | Intron (SNP) | VAF 17/46 reads (37%) | catalogued as COSV99829872; called by muse, mutect2, varscan2
- PAK6 | c.-117-825G>T | Intron (SNP) | VAF 10/17 reads (59%) | called by muse, mutect2, varscan2
- PPP2R5C | c.93+23086G>A | Intron (SNP) | VAF 17/58 reads (29%) | catalogued as rs543228069; called by muse, mutect2, varscan2
- RSPH1 | c.*2A>T | 3'UTR (SNP) | VAF 8/20 reads (40%) | called by muse, mutect2, varscan2
